Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A8WC, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A8WC-01A (Primary Tumor).

Specimen Date/Time:

ICD-O-3

(adenocarcinoma NOS 8140/3

Site Esophagus, distal third
C15.5

p c 3/31/14

DIAGNOSIS

- (A) ESOPHAGUS, DISTAL, TUMOR, BIOPSY:
INVASIVE, MODERATELY DIFFERENTIATED ADENOCARCINOMA.
No distinctive-type of Barrett mucosa identified.

GROSS DESCRIPTION

- (A) DISTAL ESOPHAGEAL TUMOR – Multiple light gray and pink fragments of soft tissue (0.8 x 0.3 x 0.3 cm in aggregate).
Entirely submitted in A.

BIOMARKER TESTING

Tumor block: A1

CLINICAL HISTORY

Esophageal carcinoma.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

. These tests have not been

-----END OF REPORT-----

Source: NCI Genomic Data Commons file f6ffdaee-2f73-435e-be9a-ab8419c7abfd (TCGA-R6-A8WC.F8CD8721-D488-428E-9CBE-6F07FF1EF14F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).